Surgical pathology report (de-identified scan), TCGA case TCGA-D3-A1Q6, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site MD Anderson, specimen TCGA-D3-A1Q6-07A (Additional Metastatic).

[page 1 of 2]
DIAGNOSIS

additional met
Procured same time
as primary

(A) RIGHT UPPER ARM, SKIN ELLIPSE:

MALIGNANT MELANOMA INVOLVING DERMIS AND SUBCUTANEOUS TISSUE, EXCISION.
(SEE COMMENT)

(B) ADDITIONAL MEDIAL MARGIN:

Skin and subcutaneous tissue. Melanoma not identified.

(C) ADDITIONAL LATERAL MARGIN:

Skin and subcutaneous tissue. Melanoma not identified.

100-0-3

malignant melanoma, NOS 8720/3

Site: lymph node, axillary C77.3

hw
11/7/14

✱ (D) LEVELS 1, 2, AND 3 AXILLARY:

MALIGNANT MELANOMA METASTATIC TO ONE OF TWENTY-TWO LYMPH NODES (1/22).
TUMOR SIZE 50.0 X 30.0 MM.
Extracapsular extension present.

(E) ADDITIONAL LEVEL #2:

Three lymph nodes negative for melanoma (0/3).

Entire report and diagnosis completed by

COMMENT

In specimen A, there is no obvious intraepidermal component. A recurrent or metastatic origins are possible. If this were to be a primary lesion, it would correspond to a Clark level V, at least 50.0 mm in Breslow thickness.

GROSS DESCRIPTION

(A) 2 CM, WIDE LOCAL EXCISION MELANOMA, RIGHT UPPER ARM (LONG STITCH-LATERAL, SHORT STITCH-SUPERIOR) - An 11.5 x 6.0 cm ellipse of skin and excised to a depth of 1.6 cm).

On the skin surface there is a 6.0x 5.0 x 4.0 cm, polypoid mass. The surface of the mass is covered gray-tan necrotic material. Grossly, the mass is 1.0 cm from the lateral resection margin, 1.8 cm from medial resection margin, 3.0 cm from the superior tip, and 4.5 cm from the inferior tip. The cut surface of the mass shows extensive necrosis with focal areas of black-tan tissue. Grossly, the tumor invaded the superficial dermis is 0.6 cm from the deep resection margin. No satellite nodules are identified. The rest of the skin surface is grossly unremarkable.

INK CODE: Blue-medial resection margin; yellow-lateral resection margin; black-deep resection margin.

SECTION CODE: A1, superior tip; A2, inferior tip; A3, representative sections from skin superior to the mass; A4, representative section from the skin inferior to the mass; A5, tumor with closest medial resection margin and deep resection margin; A6, tumor with closest lateral resection margin and deep resection margin; A7, A8, tumor with closest deep resection margin; A9-A14, representative sections from the tumor.

(B) ADDITIONAL MEDIAL MARGIN, SHORT STITCH SUPERIOR, LONG STITCH TRUE MEDIAL MARGIN) - A 11.0 x 1.3 cm ellipse of skin excised to a depth of 0.8 cm. The skin is grossly unremarkable. The true medial margin is inked in blue.

SECTION CODE: B1, superior tip; B2, inferior tip; B3-B6, the entire new medial margin, en face, from superior to inferior.

[page 2 of 2]
(C) ADDITIONAL LATERAL MARGIN (LONG STITCH TRUE LATERAL MARGIN, SHORT STITCH SUPERIOR) - A 11.5 x 1.5 cm ellipse of skin and excised to a depth of 0.9 cm. The specimen is grossly unremarkable. The true lateral margin is inked with blue.

SECTION CODE: C1, superior tip; C2, inferior tip; C3-C7, the entire new lateral margin en face from superior to inferior.

(D) LEVELS 1, 2 AND 3 AXILLARY CONTENTS, SUTURE APEX - An oriented irregular fragment of adipose tissue measuring 13.0 x 13.0 x 2.0 cm. The specimen is oriented as suture at apex. The specimen is serially sectioned and 19 lymph nodes are identified ranging from (0.2 x 0.2 x 0.2 to 5.0 x 3.0 x 3.0 cm). The cut surface of the largest lymph node is slightly firm, dark brown.

SECTION CODE: D1, five lymph nodes; D2, three lymph nodes; D3, two lymph nodes; D4, one lymph node bisected; D5, one lymph node bisected; D6, D7, one lymph node bisected; D8, D9, one lymph node bisected; D10, one lymph node serially sectioned; D11, D12, one lymph node serially sectioned; D13, D14, one lymph node serially sectioned; D15, one lymph node - apex area marked by the stitch; D16-D22, largest lymph node serially sectioned.

(E) ADDITIONAL LEVEL 2 - An irregular fragment of adipose tissue measuring 4.0 x 2.0 x 0.4 cm. Three lymph nodes are identified ranging in size from 0.3 x 0.2 x 0.1 cm to 0.5 x 0.3 x 0.2 cm.

SECTION CODE: E, three lymph nodes.

CLINICAL HISTORY

None given.

SNOMED CODES

T-02610, M-87203, M-87206, T-C4710

"Some tests reported here may have been developed and performance characteristics determined by

These tests have not been specifically cleared or approved by the U.S. Food and Drug Administration."

Released by:

-----END OF REPORT-----

Source: NCI Genomic Data Commons file a273d38c-4126-4c28-900a-619b40537c53 (TCGA-D3-A1Q6.7E74D698-CA50-40D9-8A06-6CECFD8580DA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).